Somatic mutation profile of tumor specimen ALCH-B3FU-TTP1-A (aliquot ALCH-B3FU-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3FU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.2 years (25,658 days).
Specimen ALCH-B3FU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0dbe256-f057-4add-b7bf-9742ffaff3fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FU-NB1-A (Blood Derived Normal), aliquot ALCH-B3FU-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/993b7a65-917a-480a-8fd3-3e12e9a2e98f

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, 3'UTR 2, RNA 1, 5'Flank 1, Intron 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BFSP2 | c.858C>A p.N286K | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV56590343; called by muse, mutect2
- DSC3 | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 15/494 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64574517; called by muse, mutect2
- DSG1 | c.2723C>T p.S908F | Missense Mutation (SNP) | VAF 32/1234 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs992648350; called by muse, mutect2
- F11R | c.895G>T p.V299L | Missense Mutation (SNP) | VAF 25/538 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1156990366; called by muse, mutect2
- F7 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 18/532 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1292824659; called by muse, mutect2
- FLG | c.4703C>A p.A1568D | Missense Mutation (SNP) | VAF 41/829 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as COSV100911542; called by muse, mutect2
- IGHG4 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395502712; called by muse, mutect2
- IGHV3-38 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 17/594 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.176); catalogued as rs1302659724; called by muse, mutect2
- MTNR1A | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 33/1100 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56155424; called by muse, mutect2
- NLGN4X | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 19/486 reads (4%) | catalogued as COSV52006362; called by muse, mutect2
- NPAP1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV61510405; called by mutect2, varscan2
- PCDHB2 | c.1638G>T p.E546D | Missense Mutation (SNP) | VAF 32/1047 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV50596181, COSV50605192; called by muse, mutect2
- RUNX3 | c.980C>A p.P327Q | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58245639; called by muse, mutect2
- RUVBL2 | c.796G>T p.G266W | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668999; called by muse, mutect2
- ABCB1 | c.2354C>A p.T785N | Missense Mutation (SNP) | VAF 39/1338 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACHE | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 18/548 reads (3%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADD2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 15/387 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- AOX1 | c.2926T>A p.C976S | Missense Mutation (SNP) | VAF 23/700 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- BLVRA | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 46/1286 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CATSPER3 | c.728T>C p.L243S | Missense Mutation (SNP) | VAF 31/989 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.13); called by muse, mutect2
- CLEC11A | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 21/386 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.017); called by muse, mutect2
- DMBT1 | c.521A>T p.H174L | Missense Mutation (SNP) | VAF 34/807 reads (4%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.736); called by muse, mutect2
- DNTTIP1 | c.724-2A>G p.X242_splice | Splice Site (SNP) | VAF 23/452 reads (5%) | called by muse, mutect2
- DUOX2 | c.3173A>T p.D1058V | Missense Mutation (SNP) | VAF 30/953 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2
- FUT9 | c.564G>T p.L188F | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.337); called by muse, mutect2
- GDF2 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 26/617 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- KCNT2 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.574); called by muse, mutect2
- MYH6 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- MYH9 | c.803C>G p.A268G | Missense Mutation (SNP) | VAF 33/1142 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- NLRP2 | c.2888G>T p.G963V | Missense Mutation (SNP) | VAF 22/645 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- NLRP3 | c.3069G>T p.K1023N | Missense Mutation (SNP) | VAF 34/1302 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2
- OR13C9 | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- OR6M1 | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDHB4 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); called by muse, mutect2
- PCDHGA1 | c.2333C>T p.T778I | Missense Mutation (SNP) | VAF 29/1007 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); called by muse, mutect2
- PSD | c.583G>T p.G195W | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- STARD8 | c.90del p.I31Sfs*53 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- CPS1 | c.3354T>C p.F1118= | Silent (SNP) | VAF 17/525 reads (3%) | called by muse, mutect2
- IGFN1 | c.2703C>A p.V901= (on ENST00000295591 / NM_001367841.1; = p.V3358= on NM_001164586.2) | Silent (SNP) | VAF 18/418 reads (4%) | catalogued as COSV55182293; called by muse, mutect2
- PKLR | c.888C>A p.A296= | Silent (SNP) | VAF 55/570 reads (10%) | catalogued as COSV61362578; called by muse, mutect2
- SLC27A3 | c.2115A>T p.G705= (on ENST00000271857; = p.G577= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/486 reads (5%) | called by muse, mutect2
- SLFN14 | c.1800A>T p.T600= | Silent (SNP) | VAF 22/762 reads (3%) | called by muse, mutect2
- TBC1D9B | c.3162G>T p.V1054= (on ENST00000356834 / NM_198868.3; = p.V1037= on NM_015043.4) | Silent (SNP) | VAF 24/520 reads (5%) | called by muse, mutect2
- TRIM48 | c.528G>T p.V176= | Silent (SNP) | VAF 28/796 reads (4%) | called by muse, mutect2
- WDR36 | c.57G>T p.A19= | Silent (SNP) | VAF 18/343 reads (5%) | called by muse, mutect2
- ZNF579 | c.1113C>T p.D371= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- FDFT1 | chr8:11802414 G>A | 5'Flank (SNP) | VAF 10/224 reads (4%) | catalogued as rs909830653, COSV55043196; called by muse, mutect2
- FKBP15 | c.*4232T>A | 3'UTR (SNP) | VAF 40/679 reads (6%) | called by muse, mutect2
- FOXRED1 | c.86-16T>C | Intron (SNP) | VAF 21/799 reads (3%) | called by muse, mutect2
- MYADML | n.1075C>A | RNA (SNP) | VAF 16/536 reads (3%) | called by muse, mutect2
- SLC29A3 | c.*722T>A | 3'UTR (SNP) | VAF 23/505 reads (5%) | called by muse, mutect2
